MMRF case MMRF_1655 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/2cd3dbf9-9315-4a6d-b2d8-5f3b2e118308

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 63 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 63.4 years (23,145 days); ISS stage: III; Days to last known disease status: 1,199 days (3.3 years); Days to last follow up: 1,199 days (3.3 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 162 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 77 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 84 days; Days to treatment end: 162 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 225 days; Days to treatment end: 225 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 226 days; Days to treatment end: 226 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 318 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -7 (ECOG 2): M Protein 4.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.56 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 346 mg/dL; Immunoglobulin A 62.1 g/L; Beta 2 Microglobulin 18.2 µg/mL; Lactate Dehydrogenase 3.07 µkat/L; Hemoglobin 5.27 mmol/L; Leukocytes 3.2 ×10⁹/L; Absolute Neutrophil 1.1 ×10⁹/L; Platelets 97 ×10⁹/L; Creatinine 95 µmol/L; Blood Urea Nitrogen 7.6 mmol/L; Calcium 2.6 mmol/L; Albumin 35 g/L; Total Protein 11.3 g/dL; Glucose 5 mmol/L.
- Day 81 (ECOG 2): M Protein 2.9 g/dL; Serum Free Immunoglobulin Light Chain, Lambda 166 mg/dL; Beta 2 Microglobulin 9.42 µg/mL; Lactate Dehydrogenase 2.6 µkat/L; Hemoglobin 5.46 mmol/L; Leukocytes 3 ×10⁹/L; Absolute Neutrophil 1.5 ×10⁹/L; Platelets 210 ×10⁹/L; Creatinine 77 µmol/L; Blood Urea Nitrogen 8.4 mmol/L; Calcium 2.25 mmol/L; Albumin 36 g/L; Total Protein 9.4 g/dL; Glucose 5 mmol/L.
- Day 164 (ECOG 2): M Protein 8 g/dL; Serum Free Immunoglobulin Light Chain, Lambda 35.4 mg/dL; Beta 2 Microglobulin 2.54 µg/mL; Hemoglobin 6.63 mmol/L; Leukocytes 3.3 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 173 ×10⁹/L; Creatinine 70 µmol/L; Calcium 2.36 mmol/L; Albumin 42 g/L; Total Protein 7.4 g/dL; Glucose 5 mmol/L.
- Day 246: M Protein 5 g/dL; Hemoglobin 6.01 mmol/L; Leukocytes 2.5 ×10⁹/L; Absolute Neutrophil 1.4 ×10⁹/L; Platelets 108 ×10⁹/L; Creatinine 56 µmol/L; Blood Urea Nitrogen 1.9 mmol/L.
- Day 336 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.38 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.96 mg/dL; Beta 2 Microglobulin 2.12 µg/mL; Lactate Dehydrogenase 3.17 µkat/L; Hemoglobin 7.44 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 195 ×10⁹/L; Creatinine 60 µmol/L; Blood Urea Nitrogen 4.3 mmol/L; Calcium 2.38 mmol/L; Albumin 45 g/L; Total Protein 6.5 g/dL; Glucose 5.1 mmol/L.
- Day 429 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.93 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.21 mg/dL; Beta 2 Microglobulin 1.71 µg/mL; Lactate Dehydrogenase 2.6 µkat/L; Hemoglobin 7.25 mmol/L; Leukocytes 3.2 ×10⁹/L; Absolute Neutrophil 1.5 ×10⁹/L; Platelets 154 ×10⁹/L; Creatinine 51 µmol/L; Blood Urea Nitrogen 6.2 mmol/L; Calcium 2.34 mmol/L; Albumin 43 g/L; Total Protein 6.6 g/dL; Glucose 6.3 mmol/L.
- Day 513 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.55 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.93 mg/dL; Beta 2 Microglobulin 2.39 µg/mL; Lactate Dehydrogenase 2.82 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 2.1 ×10⁹/L; Absolute Neutrophil 1 ×10⁹/L; Platelets 115 ×10⁹/L; Creatinine 55 µmol/L; Blood Urea Nitrogen 5.6 mmol/L; Calcium 2.29 mmol/L; Albumin 43 g/L; Total Protein 6.6 g/dL; Glucose 5.8 mmol/L.
- Day 766 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.05 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.56 mg/dL; Beta 2 Microglobulin 1.48 µg/mL; Lactate Dehydrogenase 2.45 µkat/L; Hemoglobin 7.13 mmol/L; Leukocytes 2.7 ×10⁹/L; Absolute Neutrophil 1.2 ×10⁹/L; Platelets 143 ×10⁹/L; Creatinine 89 µmol/L; Blood Urea Nitrogen 6.2 mmol/L; Calcium 2.3 mmol/L; Albumin 42 g/L; Total Protein 6.5 g/dL; Glucose 5.2 mmol/L.
- Day 849 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.24 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.96 mg/dL; Beta 2 Microglobulin 1.51 µg/mL; Lactate Dehydrogenase 2.5 µkat/L; Hemoglobin 6.82 mmol/L; Leukocytes 2.6 ×10⁹/L; Absolute Neutrophil 1.4 ×10⁹/L; Platelets 191 ×10⁹/L; Creatinine 62 µmol/L; Blood Urea Nitrogen 5.9 mmol/L; Calcium 2.27 mmol/L; Albumin 39 g/L; Total Protein 6.3 g/dL; Glucose 5.6 mmol/L.
- Day 946: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.86 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.94 mg/dL; Beta 2 Microglobulin 1.74 µg/mL; Lactate Dehydrogenase 3.48 µkat/L; Hemoglobin 7.13 mmol/L; Leukocytes 2.7 ×10⁹/L; Absolute Neutrophil 1.2 ×10⁹/L; Platelets 143 ×10⁹/L; Creatinine 77 µmol/L; Blood Urea Nitrogen 5.9 mmol/L; Calcium 2.37 mmol/L; Albumin 42 g/L; Total Protein 6.7 g/dL; Glucose 5.2 mmol/L.
- Day 1,031 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.41 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.7 mg/dL; Beta 2 Microglobulin 1.61 µg/mL; Lactate Dehydrogenase 2.75 µkat/L; Hemoglobin 7.13 mmol/L; Leukocytes 2.8 ×10⁹/L; Absolute Neutrophil 1.5 ×10⁹/L; Platelets 149 ×10⁹/L; Creatinine 70 µmol/L; Blood Urea Nitrogen 6.6 mmol/L; Calcium 2.36 mmol/L; Albumin 41 g/L; Total Protein 6.6 g/dL; Glucose 6 mmol/L.
- Day 1,115: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.58 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.5 mg/dL; Beta 2 Microglobulin 1.64 µg/mL; Lactate Dehydrogenase 2.87 µkat/L; Hemoglobin 7.25 mmol/L; Leukocytes 2.7 ×10⁹/L; Absolute Neutrophil 1.4 ×10⁹/L; Platelets 164 ×10⁹/L; Creatinine 70 µmol/L; Blood Urea Nitrogen 5.6 mmol/L; Calcium 2.36 mmol/L; Albumin 42 g/L; Total Protein 6.8 g/dL; Glucose 4.9 mmol/L.
- Day 1,199: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.53 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.3 mg/dL; Beta 2 Microglobulin 1.67 µg/mL; Lactate Dehydrogenase 2.8 µkat/L; Hemoglobin 7.56 mmol/L; Leukocytes 2.8 ×10⁹/L; Absolute Neutrophil 1.4 ×10⁹/L; Platelets 159 ×10⁹/L; Creatinine 67 µmol/L; Blood Urea Nitrogen 6.2 mmol/L; Calcium 2.27 mmol/L; Albumin 43 g/L; Total Protein 6.8 g/dL; Glucose 5 mmol/L.

Other clinical attributes
- Day -7: Weight: 60 kg; Height: 170 cm.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples)
- Sample MMRF_1655_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -7 days.
- Sample MMRF_1655_1_PB_CD138pos: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS; Days to sample procurement: -7 days.
- Sample MMRF_1655_1_PB_CD3pos: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -7 days.
